Somatic mutation profile of tumor specimen MP2PRT-PAUHAP-TBP1-C (aliquot MP2PRT-PAUHAP-TBP1-C-1-0-D-A835-36) from MP2PRT case MP2PRT-PAUHAP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (883 days).
Specimen MP2PRT-PAUHAP-TBP1-C: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3f64725-a0a1-443f-a0a0-8abf732378ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUHAP-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUHAP-NM1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c86dcfa1-803c-4dd4-bbbe-a4c96cd6ab7b

The open-access MAF lists 7 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Missense Mutation 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SEMA3G | c.1606C>T p.R536W | Missense Mutation (SNP) | VAF 71/809 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs914361173; called by muse, mutect2
- PIEZO2 | c.167C>G p.T56R | Missense Mutation (SNP) | VAF 33/271 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- RASA1 | c.1696G>C p.E566Q | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GALNT13 | c.1659C>T p.T553= | Silent (SNP) | VAF 42/419 reads (10%) | called by muse, mutect2, varscan2
- LDHD | c.1071C>A p.A357= | Silent (SNP) | VAF 55/594 reads (9%) | called by muse, mutect2
- TULP4 | c.2625G>A p.T875= | Silent (SNP) | VAF 49/457 reads (11%) | catalogued as rs539810890; called by muse, mutect2, varscan2
- SLITRK4 | c.*254C>T | 3'UTR (SNP) | VAF 23/154 reads (15%) | called by muse, mutect2, varscan2
